HCMI case HCM-BROD-0230-C25 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Pancreas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/53159c56-0604-455c-8efc-db9cdaa7642c

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1933; Vital status: Dead; Days to death: 730 days (2.0 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C78.2; Tissue or organ of origin: Pancreas, NOS; Site of resection or biopsy: Pleura, NOS; Classification of tumor: metastasis; Age at diagnosis: 83.0 years (30,305 days); AJCC staging edition: 7th; AJCC clinical stage: Stage IV; AJCC pathologic M: M1; AJCC pathologic stage: Stage IV; Metastasis at diagnosis: Metastasis, NOS; Prior treatment: Yes; Sites of involvement: Pleura.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine + Nab-paclitaxel; Treatment intent type: Neoadjuvant; Days to treatment start: 586 days (1.6 years).
   Treatment given: Treatment type: Targeted Molecular Therapy; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 673 days (1.8 years); Days to treatment end: 708 days (1.9 years).
   Treatment given: Treatment type: Targeted Molecular Therapy; Treatment intent type: Neoadjuvant.
   Recorded as not given: adjuvant Chemotherapy, for residual disease; adjuvant Immunotherapy (Including Vaccines), for residual disease; neoadjuvant Radiation Therapy, NOS; Surgery, NOS, for initial diagnosis.

Follow-up (2 entries)
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Pleura, NOS; Days to progression: 0 days.
- Days to follow up: 723 days (2.0 years); Disease response: Stable Disease; Progression or recurrence: No.

Exposures
- Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Alcohol intensity: Occasional Drinker.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples)
- Sample HCM-BROD-0230-C25-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
- Samples HCM-BROD-0230-C25-85C, HCM-BROD-0230-C25-85D (2 with the same recorded description): Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 5.
